Gene-level copy-number profile of tumor specimen ALCH-B36F-TTP1-A from ALCHEMIST case ALCH-B36F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.8 years (21,123 days).
Specimen ALCH-B36F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8de12d1-803a-4c93-b7c2-9a8ecd70b2e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36F-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,315 have no estimate.
https://portal.gdc.cancer.gov/files/9ce35038-daf7-48f6-9688-b33ad7375671

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 426; copy number 2: 55,255; copy number 3: 2,486; copy number 4: 97; copy number 5: 14; copy number 6: 11; copy number 8: 1; copy number 9: 4; copy number 10: 6; copy number 12: 6; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:2,752,131–2,755,397, 1 gene: C5orf38.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,523,860–144,593,652, 4 genes, copy number 6: RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F.
- chr1:149,290,513–149,556,361, 5 genes, copy number 6 (within-gene range 6–26): 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr7:74,773,962–74,789,376, 1 gene, copy number 9: NCF1.
- chr7:75,391,955–75,410,996, 2 genes, copy number 10–14 (within-gene range 3–14): AC211486.1, TRIM73.
- chr9:60,914,407–61,453,030, 12 genes, copy number 5–10: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,868,727–61,911,022, 3 genes, copy number 5–6: AL391987.3, Y_RNA, FAM242E.
- chr9:62,266,319–62,376,836, 6 genes, copy number 12 (within-gene range 6–12): AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1.
- chr9:68,302,867–68,330,626, 3 genes, copy number 9 (within-gene range 2–9): FOXD4L3, AL353608.3, AL353608.1.
- chr14:21,459,020–21,511,342, 3 genes, copy number 5: RAB2B, TOX4, METTL3.
- chr19:30,219,666–30,228,715, 1 gene, copy number 8 (within-gene range 2–8): AC005597.1.
- chr19:55,528,611–55,537,133, 1 gene, copy number 5: SBK2.
- chr20:35,615,829–35,621,094, 1 gene, copy number 5: SPAG4.
- chr22:21,473,000–21,517,533, 1 gene, copy number 5: PI4KAP2.

Autosomal genes at a single copy (total copy number 1): 423. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
